Somatic mutation profile of tumor specimen C3L-00982-01 (aliquot CPT0124160006) from CPTAC case C3L-00982, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.5 years (23,210 days).
Specimen C3L-00982-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae60b6f-dc87-4eed-8c37-51948baf8d22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00982-31 (Blood Derived Normal), aliquot CPT0128480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a0bcce1-e10c-4c80-815a-0440d09fdfd5

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 24/555 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV60005247; called by muse, mutect2
- BPNT2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1038937444; called by muse, mutect2
- FAM83B | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.637); catalogued as COSV60925344; called by muse, mutect2
- HMCN1 | c.12533A>G p.Y4178C | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV54904974; called by muse, mutect2
- PDZRN4 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 69/662 reads (10%) | SIFT deleterious, low confidence (0.01); catalogued as rs1204205772; called by muse, mutect2, varscan2
- PI3 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 65/663 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs148103941, COSV54783624; called by muse, mutect2
- PLA2G6 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 55/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs144012369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R3B | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs201641619; called by muse, mutect2
- RNF220 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); catalogued as COSV100698677; called by muse, mutect2
- TENM2 | c.1354G>A p.E452K (on ENST00000518659 / NM_001122679.2; = p.E220K on NM_001080428.3) | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as COSV69134624; called by muse, mutect2
- ADRA2B | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARSI | c.883T>A p.S295T | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CCNH | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- COL6A3 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CXCR2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2
- FLNB | c.1927T>A p.Y643N | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- GTF3C1 | c.4936C>G p.L1646V | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IMMT | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- JAK3 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 43/532 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2
- MPZL1 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MXRA5 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- OTOP3 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.924); called by muse, mutect2
- PALD1 | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- PCDHA8 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.043); called by muse, mutect2
- SOAT2 | c.370T>G p.Y124D | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA3 | c.1140C>T p.F380= | Silent (SNP) | VAF 42/533 reads (8%) | catalogued as rs1366244457; called by muse, mutect2
- ARHGAP21 | c.1596T>C p.T532= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs1565031983; called by muse, mutect2
- CHRNA2 | c.150G>T p.P50= | Silent (SNP) | VAF 62/868 reads (7%) | catalogued as rs758848783, COSV99532400; ClinVar: likely benign; called by muse, mutect2
- DDX60L | c.3093T>C p.C1031= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- HCN1 | c.1074C>T p.C358= | Silent (SNP) | VAF 57/641 reads (9%) | called by muse, mutect2
- KNTC1 | c.1386A>G p.L462= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- NLRP12 | c.624G>A p.E208= | Silent (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- PCDHA8 | c.852T>G p.L284= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- PHLDA1 | c.183C>T p.G61= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- RBM42 | c.927G>T p.L309= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- SLC12A6 | c.915T>C p.D305= (on ENST00000354181 / NM_001365088.1; = p.D254= on NM_005135.2) | Silent (SNP) | VAF 38/321 reads (12%) | catalogued as COSV51626804; called by muse, mutect2, varscan2
- C8orf82 | c.205+37C>T | Intron (SNP) | VAF 14/266 reads (5%) | catalogued as rs1312703717, COSV52771707; called by muse, mutect2
- SMC3 | c.-35G>T | 5'UTR (SNP) | VAF 29/282 reads (10%) | catalogued as rs374449319; called by muse, mutect2, varscan2
